CGCI case HTMCP-01-01-00012 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8b6e985e-e77a-441b-89b0-2f80c7adc209

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 39 years; Vital status: Dead; Days to death: 9 days.

Diagnoses (2)
1. Primary diffuse large B-cell lymphoma of the CNS (the primary disease): ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 39.6 years (14,469 days); Year of diagnosis: 1997; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage I; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: No; Prior malignancy: yes; Prior treatment: No; Days to last follow up: 9 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Brain; Sites of involvement: Brain, NOS.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.
2. Kaposi sarcoma: Classification of tumor: Prior primary.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 4.
- Days to follow up: 9 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day -243.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Lactate Dehydrogenase 393 [Blood test normal range upper: 190].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day -243: Comorbidities: HIV/AIDS.
- Day -243: Risk factors: HIV/AIDS.
- Day 0: Risk factors: Mycobacterium avium Complex.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Risk factors: Staphylococcus aureus.
- Day 0: Comorbidities: Staphylococcus aureus.
- Day 0: Risk factors: Pneumocystis Pneumonia.
- Day 0: Comorbidities: Mycobacterium avium Complex.
- Day 0: Comorbidities: Pneumocystis Pneumonia.
- Day 0: Comorbidities: Cryptococcal Meningitis.
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 0: Risk factors: Cryptococcal Meningitis.
- Day 0: CD4 count: 4; Haart treatment indicator: Yes.
- Day 0: AIDS risk factors: Cryptococcosis.
- Day 9: Nadir CD4 count: 4.

Biospecimens (3 samples)
- Sample HTMCP-01-01-00012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-01-00012-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-01-00012-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Primary DLBCL of the CNS; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: Year of HIV diagnosis: 1996; Cd4 counts at diagnosis: 4; Prior aids conditions: Cryptococcosis, extrapulmonary; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact; History relevant infectious diagnosis: cyptococcal meningitis, Mycobacterium avium complex, S. aureus bacteremia, Pneumocytis pneumonia.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Primary pathology: Extranodal site involvement: 1; Method initial path diagnosis: Biopsy (all types); Lymph nodes examined: No.
- Tests performed: LDH level: 393.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-01-00012-11A-01D-347:
- % tumour top: 0
- % tumour bottom: 0
